Somatic mutation profile of tumor specimen ALCH-B1YX-TTP1-A (aliquot ALCH-B1YX-TTP1-A-1-0-D-A772-36) from ALCHEMIST case ALCH-B1YX, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 67.4 years (24,631 days).
Specimen ALCH-B1YX-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3c405a51-94fe-48a5-b9f6-52f4ce2250d2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1YX-NB1-A (Blood Derived Normal), aliquot ALCH-B1YX-NB1-A-1-0-D-A772-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3e914ee0-9d67-4c90-aed1-9111140c2844

The open-access MAF lists 94 somatic variants for this specimen: 61 protein-altering or splice-affecting, 17 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 53, Silent 17, Intron 9, Nonsense Mutation 6, 3'Flank 3, 5'Flank 3, RNA 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 194/541 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519816, COSV54062198, COSV54062802; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NFE2L2 | c.235G>C p.E79Q | Missense Mutation (SNP) | VAF 20/588 reads (3%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519922, COSV67959999, COSV67960008, COSV67960140; ClinVar: likely pathogenic; called by muse, mutect2
- ANK1 | c.982G>A p.D328N | Missense Mutation (SNP) | VAF 19/425 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1466223186; called by muse, mutect2
- BCORL1 | c.3041A>G p.H1014R | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT tolerated, low confidence (0.52); PolyPhen possibly damaging (0.583); catalogued as COSV54408704; called by muse, mutect2
- BRCA1 | c.4732G>T p.D1578Y | Missense Mutation (SNP) | VAF 9/180 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); catalogued as COSV100524280; called by muse, mutect2
- CCDC88A | c.4611C>G p.I1537M (on ENST00000436346 / NM_001365480.1; = p.I1509M on NM_018084.5) | Missense Mutation (SNP) | VAF 19/534 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as COSV55059683; called by muse, mutect2
- CTHRC1 | c.350G>A p.G117D | Missense Mutation (SNP) | VAF 12/182 reads (7%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.915); catalogued as COSV57716134; called by muse, mutect2
- EVI5 | c.86C>T p.S29F | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.691); catalogued as COSV64826999, COSV64829546; called by muse, mutect2
- FAM171B | c.375A>G p.I125M | Missense Mutation (SNP) | VAF 8/182 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs1424817310; called by muse, mutect2
- IGSF3 | c.1285C>T p.R429C (on ENST00000369486 / NM_001007237.3; = p.R449C on NM_001542.4) | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.79); catalogued as rs968366784, COSV59586064; called by muse, mutect2
- ITPRID1 | c.483C>A p.C161* | Nonsense Mutation (SNP) | VAF 20/366 reads (5%) | catalogued as COSV60074101; called by muse, mutect2
- KCNH7 | c.605C>T p.S202F | Missense Mutation (SNP) | VAF 18/308 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.359); catalogued as rs1004219995; called by muse, mutect2
- LAMA3 | c.5532G>C p.K1844N (on ENST00000313654 / NM_198129.4; = p.K235N on NM_000227.6) | Missense Mutation (SNP) | VAF 22/332 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as rs1568310403, COSV52533866, COSV52535237; called by muse, mutect2
- LRRTM3 | c.1364G>T p.R455L | Missense Mutation (SNP) | VAF 9/135 reads (7%) | SIFT tolerated (0.67); PolyPhen benign (0.201); catalogued as COSV63661689; called by muse, mutect2
- NWD2 | c.3466G>T p.E1156* | Nonsense Mutation (SNP) | VAF 11/124 reads (9%) | catalogued as COSV58758779; called by muse, mutect2
- PCDHB12 | c.2023G>A p.E675K | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.616); catalogued as COSV99506955; called by muse, mutect2, varscan2
- PCLO | c.547G>T p.E183* | Nonsense Mutation (SNP) | VAF 23/410 reads (6%) | catalogued as COSV61642872; called by muse, mutect2
- SLC12A1 | c.2380G>C p.E794Q | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.036); catalogued as COSV66794653; called by muse, mutect2
- TNN | c.2596T>A p.W866R | Missense Mutation (SNP) | VAF 19/286 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV53435421; called by muse, mutect2
- TP53 | c.854A>G p.E285G | Missense Mutation (SNP) | VAF 34/638 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as CM083790, COSV52676438, COSV53038615, COSV53625652; called by muse, mutect2
- TRPS1 | c.508G>T p.G170C (on ENST00000220888 / NM_001330599.2; = p.G183C on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/399 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.67); catalogued as COSV55248649; called by muse, mutect2
- UBE2Q2 | c.1075G>T p.V359L | Missense Mutation (SNP) | VAF 7/135 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.067); catalogued as rs1444199424; called by muse, mutect2
- ZNF777 | c.2491G>A p.E831K | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV56096450; called by muse, mutect2
- ABHD13 | c.307T>G p.L103V | Missense Mutation (SNP) | VAF 6/128 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.692); called by muse, mutect2
- ACOT9 | c.1282C>T p.P428S | Missense Mutation (SNP) | VAF 13/350 reads (4%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); called by muse, mutect2
- ALPK1 | c.2104A>T p.R702* | Nonsense Mutation (SNP) | VAF 10/78 reads (13%) | called by muse, mutect2, varscan2
- AVIL | c.2176A>G p.K726E | Missense Mutation (SNP) | VAF 14/344 reads (4%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.931); called by muse, mutect2
- CFAP44 | c.198A>T p.E66D | Missense Mutation (SNP) | VAF 26/390 reads (7%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.005); called by muse, mutect2
- CHD7 | c.6149G>T p.R2050L | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.277); called by muse, mutect2
- COL17A1 | c.2228-4C>G | Splice Region (SNP) | VAF 27/444 reads (6%) | called by muse, mutect2
- F10 | c.363T>A p.C121* | Nonsense Mutation (SNP) | VAF 20/490 reads (4%) | called by muse, mutect2
- GCC1 | c.1101G>T p.E367D | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- HECW1 | c.1424A>G p.D475G | Missense Mutation (SNP) | VAF 20/252 reads (8%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); called by muse, mutect2
- HOXD12 | c.257A>T p.Q86L | Missense Mutation (SNP) | VAF 10/163 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.105); called by muse, mutect2
- INF2 | c.2545G>C p.E849Q | Missense Mutation (SNP) | VAF 38/386 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.398); called by muse, mutect2
- ISL2 | c.313G>T p.A105S | Missense Mutation (SNP) | VAF 15/255 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.739); called by muse, mutect2
- ITSN1 | c.4697T>C p.I1566T | Missense Mutation (SNP) | VAF 20/306 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KIT | c.587T>A p.L196Q | Missense Mutation (SNP) | VAF 13/272 reads (5%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2
- LAMA5 | c.2135C>T p.P712L | Missense Mutation (SNP) | VAF 12/249 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.42); called by muse, mutect2
- MAN2C1 | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.073); called by muse, mutect2
- MROH6 | c.1119C>A p.D373E | Missense Mutation (SNP) | VAF 14/388 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.317); called by muse, mutect2
- MROH6 | c.1117G>A p.D373N | Missense Mutation (SNP) | VAF 14/396 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.018); called by muse, mutect2
- MRPS30 | c.1249G>A p.V417I | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.046); called by muse, mutect2
- NAPEPLD | c.745A>G p.T249A | Missense Mutation (SNP) | VAF 32/488 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.271); called by muse, mutect2
- NLRP5 | c.1334G>T p.G445V | Missense Mutation (SNP) | VAF 22/302 reads (7%) | SIFT tolerated (0.63); PolyPhen benign (0.03); called by muse, mutect2
- OR51A4 | c.209T>C p.M70T | Missense Mutation (SNP) | VAF 12/398 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2
- PALD1 | c.2503A>T p.R835W | Missense Mutation (SNP) | VAF 16/209 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- PDGFRA | c.883G>C p.A295P | Missense Mutation (SNP) | VAF 9/193 reads (5%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.915); called by muse, mutect2
- SERPINI2 | c.602T>C p.I201T | Missense Mutation (SNP) | VAF 14/218 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2
- SH3D19 | c.1453-1G>A p.X485_splice | Splice Site (SNP) | VAF 12/162 reads (7%) | called by muse, mutect2
- SI | c.5152C>T p.Q1718* | Nonsense Mutation (SNP) | VAF 13/320 reads (4%) | called by muse, mutect2
- SLC12A7 | c.1864G>C p.G622R | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- SOX3 | c.100T>C p.S34P | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); called by muse, mutect2
- TENT4A | c.1506G>T p.Q502H | Missense Mutation (SNP) | VAF 18/228 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.2); called by muse, mutect2
- TNFRSF8 | c.193T>A p.C65S | Missense Mutation (SNP) | VAF 15/298 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2
- TP53I11 | c.335G>A p.S112N | Missense Mutation (SNP) | VAF 9/144 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.046); called by muse, mutect2
- TPO | c.1759G>T p.G587W | Missense Mutation (SNP) | VAF 15/266 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TRIM51GP | c.1060G>C p.A354P | Missense Mutation (SNP) | VAF 14/354 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- TTN | c.96375T>G p.N32125K (on ENST00000591111; = p.N24701K on NM_003319.4) | Missense Mutation (SNP) | VAF 33/561 reads (6%) | PolyPhen probably damaging (0.961); called by muse, mutect2
- UBE3A | c.665A>G p.N222S | Missense Mutation (SNP) | VAF 21/284 reads (7%) | SIFT tolerated (0.75); PolyPhen benign (0.001); called by muse, mutect2
- ZNF736 | c.226G>T p.A76S | Missense Mutation (SNP) | VAF 16/356 reads (4%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.739); called by muse, mutect2
- ARMH1 | c.1008G>C p.T336= | Silent (SNP) | VAF 8/130 reads (6%) | called by muse, mutect2
- ATM | c.2088A>T p.G696= | Silent (SNP) | VAF 12/178 reads (7%) | catalogued as rs1555073469; ClinVar: likely benign; called by muse, mutect2
- COL1A2 | c.2289C>A p.G763= | Silent (SNP) | VAF 23/438 reads (5%) | called by muse, mutect2
- DYTN | c.85C>T p.L29= | Silent (SNP) | VAF 12/186 reads (6%) | called by muse, mutect2
- FLG | c.11844C>T p.G3948= | Silent (SNP) | VAF 40/653 reads (6%) | called by muse, mutect2
- IGF2BP1 | c.1611G>T p.V537= | Silent (SNP) | VAF 10/212 reads (5%) | called by muse, mutect2
- KCNQ3 | c.15G>T p.A5= | Silent (SNP) | VAF 5/27 reads (19%) | called by muse, mutect2, varscan2
- LRP1B | c.8553T>C p.S2851= | Silent (SNP) | VAF 9/224 reads (4%) | called by muse, mutect2
- NLRP3 | c.102G>A p.K34= | Silent (SNP) | VAF 24/430 reads (6%) | called by muse, mutect2
- OR4A47 | c.429G>T p.L143= | Silent (SNP) | VAF 6/90 reads (7%) | called by muse, mutect2
- PLCD4 | c.1782C>A p.R594= | Silent (SNP) | VAF 9/198 reads (5%) | called by muse, mutect2
- SASH3 | c.102C>G p.S34= | Silent (SNP) | VAF 10/255 reads (4%) | called by muse, mutect2
- SH3D21 | c.1962C>G p.A654= (on ENST00000453908 / NM_001162530.2; = p.A543= on NM_024676.5) | Silent (SNP) | VAF 10/212 reads (5%) | called by muse, mutect2
- TCAP | c.423C>T p.P141= | Silent (SNP) | VAF 94/207 reads (45%) | catalogued as rs1360918794; ClinVar: likely benign; called by muse, mutect2, varscan2
- UGT2B10 | c.417A>G p.L139= | Silent (SNP) | VAF 11/171 reads (6%) | catalogued as rs1233775554; called by muse, mutect2
- XKR3 | c.1146C>G p.L382= | Silent (SNP) | VAF 12/212 reads (6%) | called by muse, mutect2
- ZGRF1 | c.1425A>G p.S475= | Silent (SNP) | VAF 12/220 reads (5%) | called by muse, mutect2
- ADORA2A | c.-274-1661A>G | Intron (SNP) | VAF 14/240 reads (6%) | catalogued as rs1389920802; called by muse, mutect2
- AP002495.1 | c.436+415T>C | Intron (SNP) | VAF 4/25 reads (16%) | catalogued as rs1470170672; called by muse, mutect2, varscan2
- ASPG | chr14:104117450 A>G | 3'Flank (SNP) | VAF 13/202 reads (6%) | called by muse, mutect2
- ASPRV1 | chr2:69963460 C>A | 5'Flank (SNP) | VAF 7/87 reads (8%) | called by muse, mutect2
- BTK | chrX:101390534 T>C | 5'Flank (SNP) | VAF 14/184 reads (8%) | called by muse, mutect2
- CLPS | c.84+369T>A | Intron (SNP) | VAF 10/166 reads (6%) | called by muse, mutect2
- G6PD | chrX:154531973 G>T | 3'Flank (SNP) | VAF 6/71 reads (8%) | called by muse, mutect2
- GALNT13 | c.1396-1005C>A | Intron (SNP) | VAF 8/148 reads (5%) | catalogued as rs1200485513; called by muse, mutect2
- ITGB5 | chr3:124887734 T>A | 5'Flank (SNP) | VAF 9/52 reads (17%) | catalogued as rs1320927538; called by muse, mutect2, varscan2
- ITSN2 | c.4936+19G>T | Intron (SNP) | VAF 6/86 reads (7%) | called by muse, mutect2
- LINC00632 | n.104+2086C>A | Intron (SNP) | VAF 5/65 reads (8%) | called by muse, mutect2
- NELL1 | c.1549+54893G>A | Intron (SNP) | VAF 15/234 reads (6%) | called by muse, mutect2
- NOC2LP2 | n.503C>A | RNA (SNP) | VAF 26/354 reads (7%) | catalogued as rs770759705; called by muse, mutect2
- NT5C1B | c.1071+80C>A | Intron (SNP) | VAF 9/192 reads (5%) | called by muse, mutect2
- SLAMF8 | chr1:159840783 C>A | 3'Flank (SNP) | VAF 17/292 reads (6%) | called by muse, mutect2
- STRA6 | c.431-41G>T | Intron (SNP) | VAF 6/107 reads (6%) | called by muse, mutect2
